Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5165, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5165-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Diagnosis:

A: Adipose tissue overlying tumor, right kidney, removal

- Benign adipose tissue.
- Negative for malignancy.

B: Right kidney, right partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell subtype

Histologic grade (if applicable): Fuhrman grade 2 of 4

Tumor size (greatest dimension): 3.2 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Tumor appears to extend into capsule; perirenal adipose tissue appears negative for malignancy (see specimen A).

Gerota's fascia: Negative for malignancy (see specimen A)

Renal vein: Not applicable

Ureter: Not applicable

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: Negative for malignancy

Gerota's fascia: Negative for malignancy

Other significant findings: Tumor is < 1 mm from the surgical margin of resection.

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with a clinical diagnosis of a right renal mass.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "fat over tumor." The container holds a portion of adipose tissue that measures 4.0 x 4.5 x 1.5 cm. The specimen is unoriented. No nodules or masses are identified.

Block summary:

A1-A3 - three representative sections of adipose tissue

Container B is additionally labeled "tumor from right kidney."

Specimen fixation: formalin

Type of specimen: partial right nephrectomy

[page 2 of 2]
Side of specimen: right

Size and weight of specimen: 14.7 grams; The specimen measures 5.4 x 4.5 x 2.0 cm.

Orientation: Capsule=blue, black=parenchyma/margin of resection

Presence/absence of adrenal gland: absent

Tumor description/site: renal cortex; The tumor appears yellow in color and is well encapsulated; focal areas of red/brown discoloration are noted.

Tumor size: 3.2 x 2.1 x 2.3 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: does not grossly involve

Gerota's fascia: not present

Renal vein: not present

Ureter: not present

Other organs: not applicable

Surgical margins: The mass directly abuts the blue inked renal capsule and is located 0.1 cm away from the black inked margin of resection.

Description of kidney away from tumor: tan with no other lesions evident

Lymph nodes (hilar): not applicable

Other significant findings: none

Tissue submitted for special investigations: yes

Digital photograph taken: no

Block Summary: (Inking: blue=capsule, black=parenchyma/margin of resection)

B1-B2 - parenchyma margin, bisected

B3-B8 - three additional sections of tumor (one section every two cassettes)

B9 - representative section of normal parenchyma with transition to tumor

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed

[REDACTED]

Source: NCI Genomic Data Commons file 2eef5847-ccb6-4d32-82e0-e63e7691b7a2 (TCGA-B8-5165.0BCCB0F1-91CD-490A-B252-94BF69622DED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).